Somatic mutation profile of tumor specimen C3L-01461-01 (aliquot CPT0390120006) from CPTAC case C3L-01461, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oncocytoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: GX; Age at diagnosis: 76.1 years (27,801 days).
Specimen C3L-01461-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 255c16a6-4482-4691-8202-b1e7a1421540.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01461-31 (Blood Derived Normal), aliquot CPT0390150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4895013d-7fba-42eb-aecc-275e063abce0

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 3, Intron 2, Splice Site 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EFCAB13 | c.2393A>G p.N798S | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs137885108; called by muse, mutect2, varscan2
- GPD2 | c.274+1G>T p.X92_splice | Splice Site (SNP) | VAF 76/276 reads (28%) | catalogued as rs1558927996; called by muse, mutect2, varscan2
- HMGCR | c.1100A>G p.N367S | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs780343008; called by muse, mutect2, varscan2
- PTGR2 | c.695T>G p.V232G | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99966465; called by muse, mutect2, varscan2
- SLC16A8 | c.689G>T p.R230L | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as rs779974924; called by muse, mutect2, varscan2
- TUBB8 | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 38/558 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); catalogued as rs141675066; called by muse, mutect2
- TUBB8B | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 84/981 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); catalogued as rs755092451; called by muse, mutect2
- ACAN | c.5148T>A p.S1716R | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKZF1 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 55/237 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CIC | c.793C>G p.P265A | Missense Mutation (SNP) | VAF 130/518 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- IFNLR1 | c.1202C>A p.A401D | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- INSM2 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRIT2 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.751); called by muse, mutect2
- SPTAN1 | c.1331T>C p.V444A | Missense Mutation (SNP) | VAF 129/487 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIP11 | c.4990G>T p.E1664* | Nonsense Mutation (SNP) | VAF 65/272 reads (24%) | called by muse, mutect2, varscan2
- WDR90 | c.673C>G p.P225A | Missense Mutation (SNP) | VAF 73/276 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF263 | c.674A>G p.Y225C | Missense Mutation (SNP) | VAF 13/249 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.831); called by muse, mutect2
- C20orf194 | c.3312G>A p.E1104= | Silent (SNP) | VAF 19/183 reads (10%) | called by muse, mutect2
- LAT | c.267G>A p.G89= | Silent (SNP) | VAF 11/140 reads (8%) | called by muse, mutect2
- SCAF8 | c.963G>A p.E321= | Silent (SNP) | VAF 21/121 reads (17%) | called by muse, mutect2, varscan2
- GFOD1 | c.253+16742A>T | Intron (SNP) | VAF 12/58 reads (21%) | catalogued as COSV64953335; called by mutect2, varscan2
- INO80E | c.-53C>T | 5'UTR (SNP) | VAF 8/142 reads (6%) | catalogued as COSV54231633; called by muse, mutect2
- PDE4DIP | c.637-7693_637-7683del | Intron (DEL) | VAF 19/176 reads (11%) | called by mutect2, pindel, varscan2
